Surgical pathology report (de-identified scan), TCGA case TCGA-28-1755, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Cedars Sinai, specimen TCGA-28-1755-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

***** Addendum - Please See End of Report *****

Reason for Addendum #1: Additional studies/stains/opinion(s)

DIAGNOSIS:

A. BRAIN, RIGHT FRONTAL, BIOPSY, NCI #1:

- Glioblastoma multiforme, WHO grade IV
- 40% of tissue is necrotic
- Tumor cellularity 70%

B. BRAIN, RIGHT FRONTAL, BIOPSY, NCI #2:

- Glioblastoma multiforme, WHO grade IV
- 50% of tissue is necrotic
- 90% of tumor cellularity

C. BRAIN, RIGHT FRONTAL, BIOPSY, NCI #3:

- Glioblastoma multiforme, WHO grade IV
- 50% of tissue is necrotic
- 90% of tumor cellularity

D. BRAIN, RIGHT FRONTAL, BIOPSY, NCI #4:

- Glioblastoma multiforme, WHO grade IV
- 20% of tissue is necrotic
- 90% of tumor cellularity

E. BRAIN, RIGHT FRONTAL, BIOPSY, NCI #5:

- Glioblastoma multiforme, WHO grade IV
- 10% of tissue is necrotic
- 90% of tumor cellularity

F. BRAIN, RIGHT FRONTAL, EXCISIONAL BIOPSY:

- Glioblastoma multiforme, WHO grade IV

COMMENT:

A high percentage of tumor cells (greater than 20%) immunostaining for MGMT has been reported to be associated with a relatively diminished response to Temodar. Hence, the 40% result in this case suggests the possibility of a relatively diminished response to Temodar.

Recent studies have shown that co-expression of EGFRvIII and PTEN as detected by immunostaining was significantly correlated with a clinical response of glioblastomas to EGFR kinase inhibitors. Hence the loss of PTEN in this case suggests a diminished probability of response to EGFR-kinase inhibitors.

[page 2 of 3]
***** Addendum - Please See End of Report *****

PATIENT:

PATH #:

Retained expression of PTEN was found to be associated with a more favorable prognosis in patients with high grade gliomas. Molecular subclasses of high-grade glioma predict prognosis, delineate a pattern of disease progression, and resemble stages in neurogenesis. Cancer Cell.

Recent studies indicated an adverse prognostic significance of increased expression of laminin beta 1 and decreased expression of laminin beta 2 predicting a worse survival of patients with gliomas. between laminin-8 and glial tumor grade, recurrence, and patient survival. Accordingly, elevated expression of beta 1 and suppressed expression of beta 2 in this tumor predict more aggressive behavior.

Presence of activated (phosphorylated) p42/44 Mitogen-Activated Protein Kinase (pMAPK) has been shown to be associated with a relative resistance of glioblastoma multiforme to radiation therapy.

at Prognostic Associations of Activated Mitogen-Activated Protein Kinase and Akt Pathways in Glioblastoma.

Correspondingly, a high percentage of tumor cells immunoreactive to pMAPK antibody in this case predicts a relative resistance to radiation therapy.

The use of these tests in guiding therapy has limitations. Review of the relevant literature and clinical correlation is advised. These test results do not obligate or preclude use of the relevant therapeutic agents.

IDC2a: Selected slides were reviewed in consultation with

HISTORY: Subdural hematoma

MICROSCOPIC:

Sections disclose necrotizing malignant neoplasm composed of densely cellular proliferation of pleomorphic hyperchromatic elongate nuclei associated with numerous mitotic figures, endothelial proliferation and palisading necrosis.

IMMUNOSTAINS:

MGMT (F2): 40%
PTEN (F2): loss (0-1+)
pMAPK (F2): 20% of tumor nuclei positive and 40% of tumor cell cytoplasm is positive
Laminin beta 1 (8/411) (F2): up-regulated (3+ in endothelial cells)
Laminin beta 2 (9/421) (F2): focal perinuclear dot-like staining in endothelial cells (down-regulation)

GROSS:

A. RIGHT FRONTAL TUMOR NCI #1

Labeled with the patient's name, labeled "right frontal tumor", and received in formalin in a cassette labeled "A" with a portion of tan-red, irregular, soft hemorrhagic tissue measuring 1.2 x 1.0 x 0.4 cm. Entirely submitted.

A1. 1

B. RIGHT FRONTAL NCI #2

Labeled with the patient's name, labeled "right frontal", and received in formalin in a cassette labeled "B" are two portions of tan-white, irregular, soft tissue measuring 0.4 x 0.3 x 0.2 cm and 0.6 x 0.3 x 0.2 cm. Entirely submitted.

B1. 2

C. RIGHT FRONTAL NCI #3

Labeled with the patient's name, labeled "right frontal", and received in formalin in a white cassette labeled "C" is a red, soft, irregular portion of soft tissue measuring 1.1 x 0.6 x 0.5 cm. Entirely submitted.

[page 3 of 3]
***** Addendum - Please See End of Report *****

PATIENT: [REDACTED]

PATH #:

1. Samples are interpreted as Positive if :
- a. EGFR to CEP 7 signal ratio is ≥ 2.0 in $\geq 10\%$ of analyzed cells.
- b. When high level of polysomy ($\geq$ four copies of EGFR in $\geq 40\%$ of cells) is present.
2. Samples are interpreted as Negative if EGFR to CEP 7 signal ratio is < 2.0 or in the absence of high level of polysomy ($\geq$ four copies of EGFR).
3. Samples are considered inconclusive, requiring consult with the pathologist, when EGFR to CEP 7 signal ratio is ≥ 2.0 in $< 10\%$ of analyzed cells or when high level of polysomy ($\geq$ four copies of EGFR) is present in $< 40\%$ of cells. These cases also need to be co-read.

REFERENCES

I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file a5f3fdf2-b7a0-4378-8537-702c2bff3680 (TCGA-28-1755.BA78ABE7-49ED-4838-90E7-52D0DCC66313.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).